Somatic mutation profile of tumor specimen TARGET-20-PANTNA-09A (aliquot TARGET-20-PANTNA-09A-03D) from TARGET case TARGET-20-PANTNA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,416 days).
Specimen TARGET-20-PANTNA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c882308-55b7-4b0f-9e0b-f2f883762896.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANTNA-14A (Bone Marrow Normal), aliquot TARGET-20-PANTNA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b60fa8c-f344-459c-9554-61429413b0a6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4081A>G p.K1361E | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV64874180; called by muse, mutect2, varscan2
- NPAP1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2, varscan2
